Somatic mutation profile of tumor specimen TCGA-22-1005-01A (aliquot TCGA-22-1005-01A-01W-0782-08) from TCGA case TCGA-22-1005, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.9 years (23,322 days).
Specimen TCGA-22-1005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d51b1782-097b-41d8-a03a-5167ac5cc43f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1005-11A (Solid Tissue Normal), aliquot TCGA-22-1005-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e0d350a-bcf3-4f9f-b1ed-144bce98e4f5

The open-access MAF lists 234 somatic variants for this specimen: 178 protein-altering or splice-affecting, 47 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 47, Nonsense Mutation 11, Intron 4, Frame Shift Ins 3, RNA 2, Frame Shift Del 2, Translation Start Site 1, 3'UTR 1, 5'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1700T>G p.L567R (on ENST00000404938 / NM_001163941.2; = p.L122R on NM_178559.6) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99327916, COSV99329706; called by muse, mutect2
- ACSM2B | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 24/443 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100312502; called by muse, mutect2
- ADAD1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.325); catalogued as COSV56644668, COSV99635370; called by muse, mutect2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 13/85 reads (15%) | catalogued as rs767549806; called by mutect2, varscan2
- AHNAK | c.13121A>T p.K4374M | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946603; called by muse, mutect2
- AKAP8 | c.504dup p.Q169Afs*4 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | catalogued as rs752767200; called by pindel, varscan2
- ALDH1L2 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99310851; called by muse, mutect2
- AMPH | c.924A>T p.K308N | Missense Mutation (SNP) | VAF 89/728 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100341542; called by muse, mutect2, varscan2
- ARL6 | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.807); catalogued as rs541850084, COSV100256431; called by muse, mutect2, varscan2
- ARPP21 | c.2135C>G p.P712R | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV99491561; called by muse, mutect2, varscan2
- ARSG | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71592387; called by muse, mutect2
- ATF2 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV99908581; called by muse, mutect2
- C12orf43 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99982403; called by muse, mutect2
- C9orf135 | c.437A>C p.D146A | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101019794; called by muse, mutect2, varscan2
- CABP7 | c.426C>A p.C142* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53363135, COSV99334744; called by muse, mutect2
- CACNA1B | c.3190G>A p.V1064I | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs1300134377, COSV53141285; called by muse, mutect2
- CACNA1G | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100661564; called by muse, mutect2, varscan2
- CCDC60 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 36/812 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.316); catalogued as COSV100554885, COSV59552269; called by muse, mutect2
- CELF3 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 107/1037 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99310172; called by muse, mutect2, varscan2
- CEP170 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 18/418 reads (4%) | catalogued as COSV100316780; called by muse, mutect2
- CEP290 | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100468260; called by muse, mutect2
- CLDN25 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.707); catalogued as COSV101493589; called by muse, mutect2, varscan2
- CLEC14A | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60563792; called by muse, mutect2
- CLIP4 | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs771314138, COSV100191697; called by muse, mutect2, varscan2
- CNTNAP5 | c.3017C>A p.T1006K | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV101443288, COSV101444440; called by muse, mutect2
- COL5A2 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100880132; called by muse, mutect2
- CPSF3 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV99432664; called by muse, mutect2
- CPSF3 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as COSV99432668; called by muse, mutect2
- CYLC1 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100254352; called by muse, mutect2, varscan2
- DGKI | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99933305; called by muse, mutect2, varscan2
- DHX9 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100841333, COSV62361587; called by muse, mutect2
- DNAH8 | c.2291G>C p.S764T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); catalogued as COSV100544151; called by muse, mutect2
- DNAJC5G | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.725); catalogued as COSV99940518; called by muse, mutect2
- DSCAML1 | c.5447C>A p.S1816Y (on ENST00000321322; = p.S1756Y on NM_020693.4) | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100355442; called by muse, mutect2
- EIF2B5 | c.939G>C p.M313I (on ENST00000647909; = p.M305I on NM_003907.3) | Missense Mutation (SNP) | VAF 38/704 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as CM152486, COSV99889122; called by muse, mutect2
- EIF5A | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 36/1423 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV59747333; called by muse, mutect2
- ERCC3 | c.2027G>T p.R676L | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99573196, COSV99573204; called by muse, mutect2, varscan2
- FAM160A2 | c.2548G>T p.D850Y (on ENST00000449352 / NM_001098794.2; = p.D864Y on NM_032127.4) | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56413336; called by muse, mutect2
- FLG | c.10462C>G p.Q3488E | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV100911361, COSV64235923; called by muse, mutect2
- FNTA | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 55/846 reads (7%) | catalogued as COSV100172474; called by muse, mutect2
- FOXM1 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 59/683 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); catalogued as COSV100700819, COSV100700844; called by muse, mutect2
- GANC | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 11/281 reads (4%) | PolyPhen benign (0); catalogued as rs983406580, COSV100530675; called by muse, mutect2
- GAPDHS | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV99722267; called by muse, mutect2, varscan2
- GPR61 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV101344402, COSV68177294; called by muse, varscan2
- GPRC6A | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59953750; called by muse, mutect2
- GRID1 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 11/165 reads (7%) | catalogued as COSV100023152; called by muse, mutect2
- GRM1 | c.1891T>A p.C631S | Missense Mutation (SNP) | VAF 27/667 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV99265213; called by muse, mutect2
- HAPLN1 | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57149110; called by muse, mutect2, varscan2
- HEPACAM2 | c.886G>T p.G296W (on ENST00000394468 / NM_001039372.4; = p.G284W on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506471; called by muse, mutect2
- HOXB13 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99284831; called by muse, mutect2
- IGFBP1 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1029772778, COSV99298692; called by muse, mutect2, varscan2
- ITGA8 | c.2030G>C p.R677T | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV100958948, COSV100959068, COSV65227346; called by muse, mutect2, varscan2
- KCNC2 | c.1492C>A p.P498T | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100128530, COSV54381444; called by muse, mutect2, varscan2
- KCNH4 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV52917960; called by muse, mutect2
- KDELR2 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV51726856; called by muse, mutect2
- KDM5C | c.3413A>C p.Q1138P | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV100948977; called by muse, varscan2
- KIF5A | c.2450C>A p.P817H | Missense Mutation (SNP) | VAF 68/1066 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV54058630; called by muse, mutect2
- KIRREL1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV63288550; called by muse, mutect2, varscan2
- KLK15 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1568483222, COSV56825742, COSV56827015; called by muse, varscan2
- KRCC1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as rs150102005; called by mutect2, varscan2
- KRT25 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100379870; called by muse, mutect2
- KRT4 | c.1217C>G p.A406G | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV53407800, COSV99542797; called by muse, mutect2
- LRRTM3 | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV100791566; called by muse, mutect2, varscan2
- MARCHF11 | c.1122G>T p.L374F | Missense Mutation (SNP) | VAF 53/636 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs201724441, COSV100197677; called by muse, mutect2
- MAST2 | c.2105A>G p.Y702C | Missense Mutation (SNP) | VAF 32/403 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100787972; called by muse, mutect2
- MCUR1 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001888; called by muse, mutect2
- MFSD11 | c.874+1G>A p.X292_splice | Splice Site (SNP) | VAF 10/111 reads (9%) | catalogued as COSV100333690; called by muse, mutect2
- MFSD6 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 44/623 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99855114; called by muse, mutect2
- MRPS22 | c.861G>T p.Q287H (on ENST00000310776 / NM_001363893.1; = p.Q288H on NM_020191.4) | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV60351132; called by muse, mutect2
- MXRA5 | c.2903C>G p.S968C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.431); catalogued as COSV54252354, COSV99476336; called by muse, mutect2, varscan2
- MYH13 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 24/788 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99353221; called by muse, mutect2
- MYO1A | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100270804; called by muse, mutect2
- MYT1L | c.954C>A p.S318R | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as rs142499159, COSV101219802; called by muse, mutect2, varscan2
- NAV3 | c.3915C>A p.S1305R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57072727, COSV57086209; called by muse, mutect2
- NBAS | c.5037G>T p.E1679D | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV99868472; called by muse, mutect2
- NFASC | c.1272T>G p.S424R (on ENST00000339876 / NM_001378329.1; = p.S435R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100363381; called by muse, mutect2
- NLRP13 | c.2575T>C p.C859R | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.758); catalogued as COSV100738121; called by muse, mutect2
- NLRP3 | c.2708C>A p.S903Y | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100275673; called by muse, mutect2, varscan2
- OGT | c.2250T>A p.D750E | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV101035294; called by muse, mutect2, varscan2
- OR10G7 | c.513C>G p.N171K | Missense Mutation (SNP) | VAF 41/952 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV100389860; called by muse, mutect2
- OR11H1 | c.590C>A p.P197Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV99421716; called by mutect2, varscan2
- OR2F1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 56/943 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1021140513, COSV67331305; called by muse, mutect2
- OR2T11 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.063); catalogued as COSV100424748; called by muse, mutect2
- OR2V2 | c.319T>G p.C107G | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100080066; called by muse, mutect2
- OR4N5 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 64/984 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100374074, COSV61321295; called by muse, mutect2
- OR4P4 | c.708del p.T237Lfs*6 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | catalogued as COSV58922443; called by mutect2, pindel, varscan2
- OR5T2 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 40/539 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57588702; called by muse, mutect2
- OR6F1 | c.631T>C p.C211R | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100129066; called by muse, mutect2
- OR6K6 | c.422G>A p.C141Y (on ENST00000368144; = p.C117Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100933718; called by muse, mutect2
- P4HA3 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 26/537 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100525645; called by muse, mutect2
- PCDH15 | c.4846C>A p.R1616S (on ENST00000644397 / NM_001354429.2; = p.R1558S on NM_001142771.2) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV64748941; called by muse, mutect2
- PCDH15 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100218222; called by muse, mutect2
- PCDH15 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57372938; called by muse, mutect2
- PEG3 | c.3262G>T p.V1088F | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.942); catalogued as COSV55630903, COSV55633895; called by muse, mutect2
- PLA2G2F | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV100907902; called by muse, mutect2
- PLEKHG1 | c.4070T>A p.L1357H | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100651554, COSV62051136; called by muse, mutect2
- PNMA8B | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100885368; called by mutect2, varscan2
- POGLUT2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65682831, COSV65683716; called by muse, mutect2, varscan2
- POLQ | c.7399C>G p.Q2467E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99951974; called by muse, mutect2
- PPIP5K2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV100383618, COSV100383777; called by muse, mutect2
- PREX1 | c.2905C>A p.P969T | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906147; called by muse, mutect2
- PRSS16 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs750160856, COSV57916082; called by muse, mutect2
- PSG4 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 180/949 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV99736718; called by muse, mutect2
- PTPRB | c.218T>A p.I73K | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.005); catalogued as COSV99716630; called by muse, mutect2, varscan2
- RELN | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as rs563525929, COSV100633132; called by muse, mutect2, varscan2
- RFX4 | c.1347C>A p.S449R (on ENST00000392842 / NM_213594.3; = p.S355R on NM_032491.6) | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99985608; called by muse, mutect2
- RIMS1 | c.1808A>G p.N603S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.056); catalogued as COSV53451580; called by muse, mutect2, varscan2
- RUBCN | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as COSV99583663; called by muse, mutect2
- SEC14L3 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99307078; called by muse, mutect2
- SEC24C | c.1039A>C p.T347P | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100226671; called by muse, mutect2
- SLC12A5 | c.1559G>C p.G520A (on ENST00000454036 / NM_001134771.2; = p.G497A on NM_020708.5) | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54796023, COSV99715680; called by muse, mutect2
- SLC35G1 | c.314G>T p.C105F (on ENST00000427197 / NM_001134658.3; = p.C104F on NM_153226.4) | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.525); catalogued as COSV101004042; called by muse, mutect2, varscan2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SLC7A13 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99878709; called by muse, mutect2
- SLIT1 | c.3337T>A p.Y1113N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99821028; called by muse, mutect2
- SMARCA2 | c.2190G>C p.Q730H | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1331151656, COSV100570636; called by muse, mutect2, varscan2
- SMYD1 | c.1155C>A p.Y385* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | catalogued as COSV101352413; called by muse, mutect2
- SNRNP35 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); catalogued as COSV100644554; called by muse, mutect2
- SPEG | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs758102466, COSV56672549; called by muse, mutect2, varscan2
- SPZ1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 25/476 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99698108; called by muse, mutect2
- STAB2 | c.2492G>T p.G831V | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101185784; called by muse, mutect2, varscan2
- SUGP1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99894716; called by muse, mutect2
- SZT2 | c.8792T>G p.L2931R (on ENST00000634258 / NM_001365999.1; = p.L2874R on NM_015284.4) | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV100987025; called by muse, mutect2
- TAGLN3 | c.141dup p.G48Rfs*21 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | catalogued as rs762583525; called by mutect2, varscan2
- TDG | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99904122; called by muse, mutect2
- TGM5 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 63/518 reads (12%) | catalogued as COSV99588856, COSV99589405; called by muse, mutect2, varscan2
- TINAG | c.912C>A p.H304Q | Missense Mutation (SNP) | VAF 23/436 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs751188992, COSV99449100, COSV99451191; called by muse, mutect2
- TLR3 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57170842; called by muse, mutect2
- TMCC1 | c.1202C>T p.A401V (on ENST00000393238 / NM_001349268.2; = p.A77V on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs376957018, COSV61439847, COSV61442749; called by muse, mutect2
- TMEM100 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 14/274 reads (5%) | catalogued as COSV101448217, COSV70117897; called by muse, mutect2
- TMEM255B | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100943114; called by muse, mutect2, varscan2
- TP53BP2 | c.3326A>G p.N1109S (on ENST00000343537 / NM_001031685.3; = p.N980S on NM_005426.2) | Missense Mutation (SNP) | VAF 14/479 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100636557, COSV59066887; called by muse, mutect2
- TRIM55 | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99396684; called by muse, mutect2
- TRPC5 | c.353A>C p.Y118S | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV99460138; called by muse, mutect2, varscan2
- TUT4 | c.4421A>G p.Y1474C | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1183261400, COSV99932050; called by muse, mutect2, varscan2
- TXNL4A | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99511400; called by muse, mutect2
- USP13 | c.1729T>G p.F577V | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99830962; called by muse, mutect2
- USP9Y | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100168274; called by muse, mutect2
- VWA5A | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 26/626 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV100827803, COSV100827943; called by muse, mutect2
- WDFY3 | c.9685C>T p.Q3229* | Nonsense Mutation (SNP) | VAF 16/224 reads (7%) | catalogued as COSV99882853; called by muse, mutect2
- YIF1B | c.786C>A p.F262L (on ENST00000339413 / NM_001039673.3; = p.F247L on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100007851; called by muse, mutect2, varscan2
- ZBTB41 | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as COSV100962987, COSV66359158; called by muse, mutect2
- ZCRB1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as COSV99861222; called by muse, mutect2
- ZNF283 | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 74/456 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100161349; called by muse, mutect2, varscan2
- ZNF540 | c.1876C>G p.Q626E | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV100329589; called by muse, mutect2
- ZSCAN9 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs941676970, COSV52849899, COSV52851227; called by muse, mutect2
- ABCC5 | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.01); called by muse, mutect2
- ADCY1 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ARHGAP32 | c.1333C>A p.L445I (on ENST00000310343 / NM_001378025.1; = p.L96I on NM_014715.4) | Missense Mutation (SNP) | VAF 19/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- B3GALNT1 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- BOC | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2
- BPNT1 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CPLANE1 | c.7972G>C p.E2658Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- DGKK | c.2960A>T p.H987L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- DMD | c.9688G>T p.D3230Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENG | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2
- IGLV1-44 | c.316T>A p.Y106N | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNH5 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 28/455 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2
- KIF21A | c.1803G>T p.V601= (on ENST00000361418 / NM_001378440.1; = p.V588= on NM_017641.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- LNX1 | c.926A>T p.D309V (on ENST00000263925 / NM_001126328.3; = p.D213V on NM_032622.2) | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYH6 | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- MYH9 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.917); called by muse, varscan2
- OR9G1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- PDPR | c.2204G>A p.C735Y | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PMS1 | c.1986G>T p.L662F | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.175); called by muse, mutect2
- PSAP | c.1471G>T p.G491* | Nonsense Mutation (SNP) | VAF 44/950 reads (5%) | called by muse, mutect2
- RAPGEF6 | c.1419G>T p.K473N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SEPTIN6 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- SKIV2L | c.1132G>C p.G378R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- SLC10A1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A14 | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.169); called by muse, mutect2
- STON2 | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- SYNE1 | c.17596G>T p.E5866* (on ENST00000367255 / NM_182961.4; = p.E5795* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TACC1 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMX3 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TOMM40 | c.535del p.Q179Rfs*8 | Frame Shift Del (DEL) | VAF 49/153 reads (32%) | called by mutect2, pindel, varscan2
- TP53 | c.618_629del p.L206_N210delinsF | In Frame Del (DEL) | VAF 14/166 reads (8%) | called by mutect2, pindel
- TTC5 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 24/562 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ADAM21 | c.1746C>T p.H582= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as COSV99960749; called by muse, mutect2
- CAD | c.2364G>C p.V788= | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as COSV99254756; called by muse, mutect2
- CCDC42 | c.7C>T p.L3= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV99549739; called by muse, mutect2, varscan2
- CDH16 | c.1320A>G p.T440= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as COSV100233759; called by muse, mutect2, varscan2
- CDH23 | c.1401C>A p.I467= | Silent (SNP) | VAF 30/434 reads (7%) | catalogued as COSV99820011; called by muse, mutect2
- CHRM2 | c.72G>T p.V24= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV57772292; called by muse, mutect2
- CHRM3 | c.1494T>A p.L498= | Silent (SNP) | VAF 30/214 reads (14%) | catalogued as COSV99697954; called by muse, mutect2, varscan2
- COMMD1 | c.525G>T p.L175= | Silent (SNP) | VAF 11/240 reads (5%) | called by muse, mutect2
- CTC1 | c.3411C>T p.P1137= | Silent (SNP) | VAF 27/319 reads (8%) | catalogued as COSV100236305; called by muse, mutect2
- CYTIP | c.783C>T p.Y261= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV99938695; called by muse, mutect2, varscan2
- DAP3 | c.615A>G p.Q205= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100546425; called by muse, mutect2, varscan2
- DMD | c.7575C>T p.P2525= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- FAM98C | c.1017G>A p.Q339= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as COSV53038008; called by muse, mutect2
- GFM2 | c.1125C>G p.L375= | Silent (SNP) | VAF 17/330 reads (5%) | catalogued as COSV99714628; called by muse, mutect2
- GPR158 | c.1143T>C p.S381= | Silent (SNP) | VAF 26/382 reads (7%) | catalogued as rs775055353, COSV100893134; called by muse, mutect2
- GRIN2B | c.3069G>A p.L1023= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV101662988; called by muse, mutect2, varscan2
- GRM1 | c.2910G>A p.P970= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as rs760312188, COSV51109833; called by muse, mutect2
- HOOK1 | c.1203G>T p.R401= | Silent (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- IGHV1OR21-1 | c.282C>T p.S94= | Silent (SNP) | VAF 53/1084 reads (5%) | catalogued as rs769043817; called by muse, mutect2
- LAMB4 | c.4509G>T p.A1503= | Silent (SNP) | VAF 28/351 reads (8%) | catalogued as COSV99223502, COSV99225418; called by muse, mutect2
- LRP8 | c.2862A>C p.A954= | Silent (SNP) | VAF 17/185 reads (9%) | catalogued as COSV100036266; called by muse, mutect2
- MOGS | c.1833G>A p.L611= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- NAV3 | c.6711C>A p.T2237= (on ENST00000397909 / NM_001024383.2; = p.T2215= on NM_014903.6) | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV99888930; called by muse, mutect2, varscan2
- NECTIN2 | c.873C>G p.P291= | Silent (SNP) | VAF 99/372 reads (27%) | catalogued as COSV99374877; called by muse, mutect2, varscan2
- NES | c.2862G>T p.T954= | Silent (SNP) | VAF 16/191 reads (8%) | catalogued as COSV100957818; called by muse, mutect2
- NR2F2 | c.405C>T p.R135= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs935924408; called by muse, mutect2, varscan2
- OR4A16 | c.330C>A p.V110= | Silent (SNP) | VAF 18/516 reads (3%) | called by muse, mutect2
- OR4K5 | c.492G>T p.V164= | Silent (SNP) | VAF 50/1149 reads (4%) | catalogued as COSV100262264, COSV60005342; called by muse, mutect2
- OR5M3 | c.432T>C p.T144= | Silent (SNP) | VAF 21/290 reads (7%) | catalogued as COSV100392409; called by muse, mutect2
- PELO | c.573G>A p.Q191= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as COSV99251023; called by muse, mutect2
- POM121 | c.1026C>G p.R342= (on ENST00000434423; = p.R77= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/468 reads (4%) | catalogued as COSV99987963; called by muse, mutect2
- PRR14L | c.5640G>T p.S1880= | Silent (SNP) | VAF 30/275 reads (11%) | catalogued as COSV100392248; called by muse, mutect2, varscan2
- PVR | c.918C>T p.I306= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV99495723; called by muse, mutect2, varscan2
- RPUSD4 | c.1057C>T p.L353= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs767682841; called by muse, mutect2, varscan2
- SEMA5A | c.552C>A p.A184= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV101227605; called by muse, mutect2, varscan2
- SLC12A5 | c.1749C>A p.I583= (on ENST00000454036 / NM_001134771.2; = p.I560= on NM_020708.5) | Silent (SNP) | VAF 30/532 reads (6%) | catalogued as rs752463505, COSV99715684; called by muse, mutect2
- SLIT1 | c.3336C>T p.G1112= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs776045110, COSV99821034; called by muse, mutect2
- SORL1 | c.4155A>G p.R1385= | Silent (SNP) | VAF 68/1028 reads (7%) | catalogued as COSV99493346; called by muse, mutect2
- SPATA5L1 | c.1542G>T p.L514= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99972963; called by muse, mutect2
- TMEM178A | c.732T>C p.Y244= | Silent (SNP) | VAF 54/682 reads (8%) | catalogued as COSV99931839; called by muse, mutect2
- TMSB4X | c.117G>A p.K39= | Silent (SNP) | VAF 9/260 reads (3%) | catalogued as COSV101020336; called by muse, mutect2
- TULP1 | c.732C>T p.G244= | Silent (SNP) | VAF 41/534 reads (8%) | catalogued as rs201670161, COSV100004021; called by muse, mutect2
- VWA3B | c.393G>A p.R131= | Silent (SNP) | VAF 35/412 reads (8%) | catalogued as COSV68240674; called by muse, mutect2
- ZKSCAN8 | c.408A>T p.L136= | Silent (SNP) | VAF 22/259 reads (8%) | catalogued as COSV100362860; called by muse, mutect2
- ZNF254 | c.72G>T p.L24= | Silent (SNP) | VAF 16/309 reads (5%) | catalogued as COSV100298151; called by muse, mutect2
- ZNF749 | c.174A>G p.V58= | Silent (SNP) | VAF 15/287 reads (5%) | called by muse, mutect2
- ZPLD1 | c.96T>C p.S32= (on ENST00000466937 / NM_001329788.1; = p.S48= on NM_175056.2) | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV100083073; called by muse, mutect2
- C7orf66 | n.385A>T | RNA (SNP) | VAF 36/243 reads (15%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.123C>A | RNA (SNP) | VAF 13/207 reads (6%) | called by muse, mutect2
- KRT18P23 | chr22:44571471 G>T | 3'Flank (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- NACA | c.70+3616C>T | Intron (SNP) | VAF 20/662 reads (3%) | called by muse, mutect2
- NEBL | c.164+46504G>T | Intron (SNP) | VAF 26/402 reads (6%) | catalogued as COSV101008755; called by muse, mutect2
- PDE4D | c.455+306839G>T | Intron (SNP) | VAF 46/552 reads (8%) | catalogued as COSV100505982; called by muse, mutect2
- SEC63 | c.*1G>A | 3'UTR (SNP) | VAF 38/814 reads (5%) | catalogued as COSV100938350; called by muse, mutect2
- ST3GAL3 | c.254+9807G>A | Intron (SNP) | VAF 24/261 reads (9%) | called by muse, mutect2
- VPS11 | c.-601G>A | 5'UTR (SNP) | VAF 9/91 reads (10%) | catalogued as rs782158141; called by muse, mutect2, varscan2
